Somatic mutation profile of tumor specimen ALCH-B1OR-TTP1-A (aliquot ALCH-B1OR-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1OR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.6 years (29,803 days).
Specimen ALCH-B1OR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97900251-d42d-4e1d-9509-5a96cd97ff2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1OR-NB1-A (Blood Derived Normal), aliquot ALCH-B1OR-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cd01da6-23cf-4712-b711-c0cd666a2c5a

The open-access MAF lists 145 somatic variants for this specimen: 108 protein-altering or splice-affecting, 23 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 23, Nonsense Mutation 8, Intron 7, 3'UTR 5, Splice Site 3, In Frame Del 1, 3'Flank 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 115/487 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.863-2A>T p.X288_splice | Splice Site (SNP) | VAF 26/183 reads (14%) | hotspot (GDC flag); catalogued as CD055731, CS132644, COSV58829315, COSV58830079; called by muse, mutect2, varscan2
- ADGRE5 | c.2200A>G p.K734E (on ENST00000242786 / NM_078481.4; = p.K641E on NM_001784.5) | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs1161706924; called by muse, mutect2, varscan2
- ADGRE5 | c.2201A>C p.K734T (on ENST00000242786 / NM_078481.4; = p.K641T on NM_001784.5) | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs1410010910; called by muse, mutect2, varscan2
- AHNAK | c.2344G>T p.G782W | Missense Mutation (SNP) | VAF 47/422 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99061814; called by muse, mutect2, varscan2
- CACNG1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs550820114; called by muse, mutect2
- CAPN12 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137937350, COSV100185302; called by muse, mutect2
- CLEC2L | c.202C>A p.R68S | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV70691578; called by muse, mutect2
- COL5A2 | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 34/590 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV66408152; called by muse, mutect2
- CPA5 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as COSV100812283; called by muse, mutect2
- EGF | c.2895C>G p.H965Q | Missense Mutation (SNP) | VAF 23/397 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV54480752; called by muse, mutect2
- KCNH7 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 48/586 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs771751716, COSV59817658; called by muse, mutect2
- MIP | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57513921; called by muse, mutect2
- MUC2 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs752323302; called by muse, mutect2
- MYH1 | c.2975C>A p.T992N | Missense Mutation (SNP) | VAF 22/472 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs563867561; called by muse, mutect2
- NMD3 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1352550282; called by mutect2, varscan2
- OPRM1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200251590; called by muse, mutect2
- OR10A3 | c.812A>T p.K271M | Missense Mutation (SNP) | VAF 24/427 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100660246; called by muse, mutect2
- PCDHA12 | c.1936C>A p.R646S | Missense Mutation (SNP) | VAF 30/313 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.249); catalogued as COSV56505834; called by muse, mutect2, varscan2
- PCDHGA12 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.022); catalogued as rs1561849765; called by muse, mutect2, varscan2
- PPIL1 | c.10A>G p.I4V | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs755549469; called by muse, mutect2, varscan2
- REG3A | c.36G>C p.W12C | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59408322; called by muse, mutect2
- SIRPD | c.5C>A p.P2H | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV101064866; called by muse, mutect2, varscan2
- SLC5A1 | c.749C>A p.T250N | Missense Mutation (SNP) | VAF 30/483 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.17); catalogued as COSV99833337; called by muse, mutect2
- SOX17 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV52026094; called by muse, mutect2, varscan2
- STAB2 | c.3589G>A p.D1197N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.146); catalogued as rs1450064026, COSV101185952; called by muse, mutect2
- UNC79 | c.2533G>T p.G845* (on ENST00000393151 / NM_001346218.2; = p.G668* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 14/278 reads (5%) | catalogued as COSV56388054; called by muse, mutect2
- WIPF1 | c.454G>C p.V152L | Missense Mutation (SNP) | VAF 19/277 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV55815322; called by muse, mutect2
- ZFP57 | c.566A>T p.Y189F | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as COSV65305982; called by muse, mutect2, varscan2
- ZNF367 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV100930831; called by muse, mutect2
- ZNF441 | c.1115C>A p.A372D | Missense Mutation (SNP) | VAF 28/333 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); catalogued as rs558868530, COSV63540439; called by muse, mutect2
- ADAMTS16 | c.887T>A p.V296E | Missense Mutation (SNP) | VAF 87/547 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALDH16A1 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.752); called by muse, varscan2
- ANHX | c.275A>T p.Q92L | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- ANK1 | c.4503C>A p.D1501E | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARR3 | c.8+2_8+5del p.X3_splice | Splice Site (DEL) | VAF 13/163 reads (8%) | called by mutect2, pindel
- ASPM | c.9320G>T p.R3107L | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.363); called by muse, mutect2
- ATM | c.9167T>A p.V3056E | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- AZGP1 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 42/408 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- BACH2 | c.2211C>G p.D737E | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2
- C5orf22 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- CR1L | c.1409G>C p.C470S | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CRYBG1 | c.2617T>C p.S873P | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CWF19L2 | c.2665A>T p.T889S | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNM1 | c.1984A>C p.I662L | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- DPEP1 | c.697T>C p.F233L | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.095); called by muse, mutect2
- DYNC1H1 | c.11583G>C p.K3861N | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2
- EXD1 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 31/649 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2
- FAM83C | c.1460C>A p.T487K | Missense Mutation (SNP) | VAF 25/327 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2
- FAT2 | c.11613G>T p.M3871I | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- FLG2 | c.7037A>T p.H2346L | Missense Mutation (SNP) | VAF 33/561 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- FZD8 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.454); called by mutect2, varscan2
- GABRA1 | c.197C>A p.T66N | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- GREB1L | c.3277G>A p.D1093N | Missense Mutation (SNP) | VAF 38/605 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2
- GREB1L | c.3491G>C p.G1164A | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- GYS2 | c.791T>C p.I264T | Missense Mutation (SNP) | VAF 25/642 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2
- HTR7 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- IGKV1-27 | c.23A>T p.Q8L | Missense Mutation (SNP) | VAF 18/460 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2
- IGKV6D-41 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 34/620 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- IRAK3 | c.398C>G p.T133S | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.23); called by muse, mutect2
- ITIH2 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ITIH2 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- LAMA1 | c.1405G>T p.G469W | Missense Mutation (SNP) | VAF 62/384 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- LINGO1 | c.1058C>A p.S353* | Nonsense Mutation (SNP) | VAF 14/290 reads (5%) | called by muse, mutect2
- LPA | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 36/584 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAP7D2 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- MFSD6 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 22/285 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- MORC2 | c.1726G>T p.E576* (on ENST00000397641 / NM_001303256.3; = p.E514* on NM_014941.3) | Nonsense Mutation (SNP) | VAF 7/133 reads (5%) | called by muse, mutect2
- MTMR14 | c.1102G>C p.V368L | Missense Mutation (SNP) | VAF 25/472 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.138); called by muse, mutect2
- MYBL1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.423); called by muse, mutect2
- MYH2 | c.2940G>T p.K980N | Missense Mutation (SNP) | VAF 35/619 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- N4BP2 | c.3175A>G p.K1059E | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.214); called by muse, mutect2
- NDST3 | c.2537A>G p.H846R | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2
- NDST4 | c.2207C>A p.T736N | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- NSMF | c.1182G>C p.K394N (on ENST00000371475 / NM_001130969.3; = p.K392N on NM_015537.4) | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2
- NUDT17 | c.376+2T>G p.X126_splice | Splice Site (SNP) | VAF 22/158 reads (14%) | called by muse, mutect2, varscan2
- OFD1 | c.103dup p.T35Nfs*13 | Frame Shift Ins (INS) | VAF 73/626 reads (12%) | called by mutect2, pindel, varscan2
- PAK5 | c.1279G>T p.V427L | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.042); called by muse, mutect2
- PALM2AKAP2 | c.2250G>T p.R750S (on ENST00000259318 / NM_001136562.3; = p.R981S on NM_007203.5) | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PBDC1 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- PCDH15 | c.1409A>C p.D470A | Missense Mutation (SNP) | VAF 56/495 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD1L1 | c.4034G>T p.W1345L | Missense Mutation (SNP) | VAF 16/277 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2
- POTEC | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 72/487 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- PSMA8 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.44); called by muse, mutect2
- RAVER2 | c.173T>C p.L58P | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RBM14 | c.452A>C p.Q151P | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2
- RBM33 | c.1376A>G p.D459G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2
- RELN | c.1773G>T p.L591F | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); called by muse, mutect2
- RGS12 | c.2427G>T p.Q809H | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2
- RYR2 | c.4945G>T p.E1649* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- SAMHD1 | c.937T>A p.W313R | Missense Mutation (SNP) | VAF 48/429 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SBSN | c.1140G>A p.W380* | Nonsense Mutation (SNP) | VAF 39/282 reads (14%) | called by muse, mutect2, varscan2
- SCN8A | c.2851G>A p.A951T | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0.009); called by muse, mutect2
- SEMA6D | c.3028G>T p.D1010Y (on ENST00000316364 / NM_153618.2; = p.D948Y on NM_020858.2) | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SERPINB12 | c.1198G>T p.G400C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A19 | c.1182_1196del p.E394_A399delinsD | In Frame Del (DEL) | VAF 24/150 reads (16%) | called by mutect2, pindel
- STAG3 | c.2534T>A p.V845D | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SVEP1 | c.9801T>A p.C3267* | Nonsense Mutation (SNP) | VAF 30/207 reads (14%) | called by muse, mutect2, varscan2
- TAGLN2 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 51/439 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TCF20 | c.3519G>T p.K1173N | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.022); called by muse, mutect2
- TDRD12 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- TET1 | c.1168G>C p.G390R | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- TRIM66 | c.1774A>G p.T592A | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0.127); called by muse, mutect2
- XRCC3 | c.644T>A p.V215E | Missense Mutation (SNP) | VAF 23/427 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ZFHX3 | c.10288G>A p.E3430K | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.012); called by muse, mutect2
- ZNF382 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 18/327 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF69 | c.1255A>T p.K419* | Nonsense Mutation (SNP) | VAF 18/236 reads (8%) | called by muse, mutect2
- ZNF727 | c.1484T>A p.L495* | Nonsense Mutation (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- AVPR1A | c.1005A>G p.L335= | Silent (SNP) | VAF 27/149 reads (18%) | catalogued as COSV54546013; called by muse, varscan2
- BEND4 | c.357G>T p.P119= | Silent (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2
- CCT8L2 | c.573C>A p.I191= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV100742569; called by muse, mutect2, varscan2
- COG3 | c.609G>A p.L203= | Silent (SNP) | VAF 18/229 reads (8%) | called by muse, mutect2
- DAG1 | c.855A>T p.A285= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as COSV100444746; called by muse, mutect2, varscan2
- DENND1B | c.909A>T p.L303= | Silent (SNP) | VAF 17/191 reads (9%) | called by muse, mutect2
- DMTF1 | c.2097T>G p.V699= | Silent (SNP) | VAF 22/206 reads (11%) | called by muse, mutect2
- EDEM3 | c.30G>T p.G10= | Silent (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- EFCAB5 | c.2946G>C p.L982= | Silent (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- FLNA | c.45G>T p.A15= | Silent (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- IARS1 | c.552A>T p.A184= | Silent (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- LILRA1 | c.408C>A p.T136= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as COSV52185270; called by muse, mutect2
- MORC2 | c.1725G>T p.L575= (on ENST00000397641 / NM_001303256.3; = p.L513= on NM_014941.3) | Silent (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- OTULINL | c.234A>T p.G78= | Silent (SNP) | VAF 10/157 reads (6%) | called by muse, mutect2
- RBP3 | c.2391C>T p.C797= | Silent (SNP) | VAF 29/479 reads (6%) | catalogued as rs1555211460; called by muse, mutect2
- SALL1 | c.3945G>T p.V1315= | Silent (SNP) | VAF 27/279 reads (10%) | called by muse, mutect2, varscan2
- SLC30A3 | c.681G>A p.L227= | Silent (SNP) | VAF 37/323 reads (11%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.2928A>C p.T976= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as COSV61193650; called by muse, mutect2, varscan2
- TBCC | c.810C>T p.R270= | Silent (SNP) | VAF 37/171 reads (22%) | called by muse, mutect2, varscan2
- USH2A | c.12858C>T p.I4286= | Silent (SNP) | VAF 42/488 reads (9%) | catalogued as COSV56351925; called by muse, mutect2
- WDR87 | c.3711A>T p.G1237= | Silent (SNP) | VAF 26/189 reads (14%) | called by muse, mutect2, varscan2
- ZNF33A | c.1989C>A p.P663= (on ENST00000458705 / NM_006974.3; = p.P664= on NM_006954.2) | Silent (SNP) | VAF 19/351 reads (5%) | called by muse, mutect2
- ZNF69 | c.1257G>A p.K419= | Silent (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- ANXA8 | c.*2G>A | 3'UTR (SNP) | VAF 65/495 reads (13%) | called by muse, mutect2, varscan2
- CALCA | chr11:14967783 C>A | 3'Flank (SNP) | VAF 46/466 reads (10%) | called by muse, mutect2
- CNTN4 | c.2512-41A>T | Intron (SNP) | VAF 9/173 reads (5%) | called by muse, mutect2
- CYP2A7P1 | n.653T>A | RNA (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- HSPA12A | c.41-51C>A | Intron (SNP) | VAF 13/265 reads (5%) | called by muse, mutect2
- KCNC4 | c.*578C>G | 3'UTR (SNP) | VAF 19/410 reads (5%) | called by muse, mutect2
- MATR3 | c.*1256C>T | 3'UTR (SNP) | VAF 16/264 reads (6%) | called by muse, mutect2
- PACRG | c.613+101553G>C | Intron (SNP) | VAF 27/325 reads (8%) | called by muse, mutect2
- PIK3R2 | c.1417-49G>T | Intron (SNP) | VAF 20/456 reads (4%) | called by muse, mutect2
- POU2F2 | c.1401-156del | Intron (DEL) | VAF 28/228 reads (12%) | called by mutect2, pindel, varscan2
- RDX | c.13-416A>T | Intron (SNP) | VAF 30/248 reads (12%) | called by muse, mutect2, varscan2
- RNF10 | c.157+4431G>A | Intron (SNP) | VAF 19/284 reads (7%) | called by muse, mutect2
- SDK2 | c.*299G>A | 3'UTR (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- VAPB | c.*671G>A | 3'UTR (SNP) | VAF 60/519 reads (12%) | called by muse, mutect2, varscan2
